Somatic mutation profile of tumor specimen TCGA-K4-A4AB-01B (aliquot TCGA-K4-A4AB-01B-12D-A289-08) from TCGA case TCGA-K4-A4AB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 76.4 years (27,922 days).
Specimen TCGA-K4-A4AB-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8f258f6-c5a8-4a97-b51d-a3840aebc5aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A4AB-10A (Blood Derived Normal), aliquot TCGA-K4-A4AB-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e05cf48-2d72-40a6-9e21-0788130098fc

The open-access MAF lists 114 somatic variants for this specimen: 83 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 28, Nonsense Mutation 9, Frame Shift Del 3, Splice Site 2, RNA 2, Frame Shift Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 81/107 reads (76%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.3739C>T p.Q1247* | Nonsense Mutation (SNP) | VAF 41/164 reads (25%) | catalogued as COSV100252351; called by muse, mutect2, varscan2
- AFF4 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.042); catalogued as COSV54793726, COSV54800342; called by muse, mutect2, varscan2
- AKAP12 | c.4268C>A p.A1423E | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV53573329, COSV53576009; called by muse, mutect2, varscan2
- ARHGAP39 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as rs774404227, COSV52769011; called by muse, mutect2, varscan2
- ATG14 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1055693781, COSV55956174; called by muse, mutect2, varscan2
- ATP10A | c.3014G>T p.R1005L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63515461, COSV63516106; called by muse, mutect2, varscan2
- ATP1A3 | c.1420C>T p.R474C (on ENST00000545399 / NM_001256214.2; = p.R461C on NM_152296.5) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374426202; called by muse, mutect2, varscan2
- CAMK1D | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs200489408; called by muse, mutect2, varscan2
- CCDC178 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371081933, COSV55769182; called by muse, mutect2, varscan2
- CCDC39 | c.1825A>G p.M609V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs762805319, COSV56482166; called by muse, mutect2, varscan2
- CEP104 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.626); catalogued as COSV100986749, COSV65517010; called by muse, mutect2, varscan2
- CNOT1 | c.2849T>C p.M950T | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55315209; called by muse, mutect2, varscan2
- CSKMT | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV63473541; called by muse, mutect2, varscan2
- CTNNAL1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.564); catalogued as COSV57702381; called by muse, mutect2, varscan2
- CUTC | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65081711; called by muse, mutect2, varscan2
- CYBA | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs13306293, CD082084, COSV55368179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP11B1 | c.741G>C p.W247C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52826221, COSV52830264; called by muse, mutect2, varscan2
- DNAI4 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.407); catalogued as COSV64021426; called by muse, mutect2, varscan2
- DNTT | c.507G>A p.T169= | Splice Region (SNP) | VAF 53/174 reads (30%) | catalogued as rs768463311, COSV64522890; called by muse, mutect2, varscan2
- ERVW-1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.746); catalogued as rs753613223, COSV71259385; called by muse, mutect2, varscan2
- ESR1 | c.1082C>A p.A361E | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52787427, COSV52790229; called by muse, mutect2, varscan2
- FCGBP | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as rs1472137670; called by muse, mutect2, varscan2
- FGF23 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52975661; called by muse, mutect2, varscan2
- FOXP1 | c.664+1G>A p.X222_splice | Splice Site (SNP) | VAF 103/309 reads (33%) | catalogued as COSV59537307; called by muse, mutect2, varscan2
- FUT4 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GOLGA3 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151069773; called by muse, mutect2, varscan2
- GPATCH8 | c.2882G>C p.R961P | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV59194214; called by muse, mutect2, varscan2
- GPR20 | c.48T>A p.N16K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV66684290; called by muse, mutect2, varscan2
- H4C9 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV62889756; called by muse, mutect2, varscan2
- JADE3 | c.951G>T p.L317F | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.477); catalogued as COSV54465759, COSV54468286; called by muse, mutect2, varscan2
- KDM6A | c.3401T>C p.L1134P | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65039115; called by muse, varscan2
- KDM6B | c.4895A>G p.D1632G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs866817393, COSV99640963; called by muse, mutect2
- KMT2A | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as COSV63284573; called by muse, mutect2, varscan2
- LCORL | c.5606G>T p.C1869F (on ENST00000635767 / NM_001365665.1; = p.M260I on NM_153686.8) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.411); catalogued as COSV52269590; called by muse, mutect2, varscan2
- MAPT | c.262G>A p.E88K (on ENST00000262410 / NM_001377265.1; = p.E117K on NM_005910.5) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs373705830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOXD1 | c.1213G>T p.G405W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60943478; called by muse, mutect2, varscan2
- MUC16 | c.17590C>T p.Q5864* | Nonsense Mutation (SNP) | VAF 66/156 reads (42%) | catalogued as COSV101198908; called by muse, mutect2, varscan2
- MYO7A | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs113326082, COSV68684377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NACA | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV63269299; called by muse, mutect2, varscan2
- NXPH1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757626991, COSV68313596; called by muse, mutect2, varscan2
- OBSCN | c.11507G>A p.G3836E | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52763195; called by muse, mutect2, varscan2
- OLFML1 | c.923G>A p.W308* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100206263, COSV100206603; called by muse, mutect2, varscan2
- OPN1LW | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV64064125; called by muse, mutect2, varscan2
- OR4M1 | c.455del p.G152Afs*6 | Frame Shift Del (DEL) | VAF 80/244 reads (33%) | catalogued as rs760267821, COSV60064156; called by mutect2, varscan2
- OR5AS1 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs758620437, COSV100546206; called by muse, mutect2
- OR5L2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as COSV65723765; called by muse, mutect2, varscan2
- PDZD7 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs757382266, COSV100931574; called by muse, varscan2
- PHB2 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV54641667; called by muse, mutect2, varscan2
- PLCE1 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV53346214; called by muse, mutect2, varscan2
- PNPLA5 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as rs373979171; called by muse, mutect2, varscan2
- SEMA3A | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54867332; called by muse, mutect2, varscan2
- SIGLEC5 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV55779013; called by muse, mutect2, varscan2
- SLC27A4 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1168085285, COSV100307147; called by muse, mutect2
- SLFN5 | c.2061G>T p.Q687H | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55480664; called by muse, mutect2, varscan2
- SLTM | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV51055834; called by muse, mutect2, varscan2
- SNX33 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV57913260; called by muse, mutect2, varscan2
- SPINK7 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV51001566; called by muse, mutect2, varscan2
- SPNS1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1280604602, COSV57954340; called by muse, mutect2, varscan2
- SYNE3 | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758419026, COSV62079015; called by muse, mutect2, varscan2
- TAF11 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV63542939; called by muse, mutect2, varscan2
- TARBP1 | c.4030T>C p.F1344L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50182442, COSV50210709; called by muse, mutect2, varscan2
- TBC1D23 | c.1289C>A p.A430D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV61367545; called by muse, mutect2
- TCFL5 | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV53896281; called by muse, mutect2, varscan2
- TGFBR1 | c.806-1G>A p.X269_splice | Splice Site (SNP) | VAF 30/44 reads (68%) | catalogued as COSV66625443; called by muse, mutect2, varscan2
- TMTC4 | c.649G>A p.A217T (on ENST00000376234 / NM_001350577.2; = p.A236T on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/209 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60891911; called by muse, mutect2, varscan2
- TOP3B | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991245535, COSV64116952; called by muse, mutect2, varscan2
- TPSD1 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs376684800; called by muse, mutect2, varscan2
- TRAM1L1 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60291664; called by muse, mutect2, varscan2
- TTC7B | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs775846638, COSV60625244; called by muse, mutect2, varscan2
- UTRN | c.3064G>T p.E1022* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100839740, COSV62338133; called by muse, mutect2, varscan2
- VNN1 | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV63389687; called by muse, mutect2, varscan2
- YY1 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV51762023; called by muse, mutect2, varscan2
- ZFP2 | c.52A>G p.N18D | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV63725465; called by muse, mutect2, varscan2
- ZMIZ1 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV57893471; called by muse, mutect2, varscan2
- ZNF418 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 110/224 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV68675762; called by muse, mutect2, varscan2
- ZNF746 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV61407068; called by muse, mutect2, varscan2
- ZNF839 | c.1589C>G p.P530R (on ENST00000558850 / NM_001267827.1; = p.P646R on NM_018335.5) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.628); catalogued as COSV51757026; called by muse, mutect2, varscan2
- FAM170A | c.750del p.I251Sfs*17 | Frame Shift Del (DEL) | VAF 29/249 reads (12%) | called by mutect2, pindel, varscan2
- IGLV4-69 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- MTHFD2 | c.234dup p.P79Sfs*22 | Frame Shift Ins (INS) | VAF 76/142 reads (54%) | called by mutect2, pindel, varscan2
- RBM10 | c.1663_1667del p.P555Cfs*20 | Frame Shift Del (DEL) | VAF 21/38 reads (55%) | called by mutect2, pindel, varscan2
- BLMH | c.813G>C p.V271= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV55585059; called by muse, mutect2, varscan2
- C11orf45 | c.84G>A p.L28= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as COSV57965049; called by muse, mutect2, varscan2
- CAPN3 | c.2136C>A p.L712= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV55515654; called by muse, mutect2, varscan2
- CDH5 | c.1716C>T p.T572= | Silent (SNP) | VAF 80/174 reads (46%) | catalogued as rs112348868, COSV58517044, COSV58518395; called by muse, mutect2, varscan2
- CNTNAP2 | c.693G>A p.Q231= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV62167496; called by muse, mutect2, varscan2
- CXorf21 | c.162C>G p.L54= | Silent (SNP) | VAF 79/120 reads (66%) | catalogued as COSV100973195, COSV66762645; called by muse, mutect2, varscan2
- DPYD | c.1386A>G p.P462= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV64595011, COSV64596911, COSV64617212; called by muse, mutect2, varscan2
- DRP2 | c.405G>A p.V135= | Silent (SNP) | VAF 78/97 reads (80%) | catalogued as COSV65810059; called by muse, mutect2, varscan2
- ELK1 | c.156G>A p.K52= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV55952254; called by muse, mutect2, varscan2
- FAM193A | c.3634C>T p.L1212= (on ENST00000324666 / NM_001256666.1; = p.L1171= on NM_003704.3) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV61192931; called by muse, mutect2, varscan2
- GRIA2 | c.690T>G p.V230= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV52387694; called by muse, mutect2, varscan2
- GRIN2D | c.3420G>A p.P1140= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs765789746, COSV53518396; called by muse, mutect2, varscan2
- HDAC5 | c.3033C>T p.I1011= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV52242310; called by muse, mutect2, varscan2
- KAT2B | c.1176G>C p.G392= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV55428388; called by muse, mutect2, varscan2
- KCNH2 | c.2340C>T p.Y780= | Silent (SNP) | VAF 47/143 reads (33%) | catalogued as COSV51135492; called by muse, mutect2, varscan2
- NAA11 | c.330C>T p.H110= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs774663471, COSV54514307; called by muse, mutect2, varscan2
- NAXE | c.123G>A p.L41= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV63992605; called by muse, mutect2, varscan2
- NCR2 | c.399T>G p.S133= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV66100485; called by muse, mutect2, varscan2
- NF1 | c.6735A>G p.Q2245= (on ENST00000358273 / NM_001042492.3; = p.Q2224= on NM_000267.3) | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as rs1279608530, COSV62199837; called by muse, mutect2, varscan2
- NOVA1 | c.642C>T p.I214= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as COSV57475277; called by muse, mutect2, varscan2
- QKI | c.573G>A p.K191= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV51692273; called by muse, mutect2, varscan2
- SERPINB3 | c.123C>T p.V41= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV52190711; called by muse, mutect2, varscan2
- SLC7A8 | c.1413C>T p.H471= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV57553733, COSV57553882; called by muse, mutect2, varscan2
- STAP2 | c.267G>A p.L89= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV74075451; called by muse, mutect2, varscan2
- TBX10 | c.322C>T p.L108= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100039614, COSV56875418; called by muse, mutect2, varscan2
- TMEM185A | c.939G>A p.P313= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs1429270978; called by mutect2, varscan2
- WBP2NL | c.24C>T p.T8= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1356158625, COSV52171213, COSV52171675; called by muse, mutect2, varscan2
- ZNF131 | c.70T>C p.L24= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as rs1266872215, COSV61002180; called by muse, mutect2, varscan2
- ANKRD23 | c.*2C>A | 3'UTR (SNP) | VAF 8/11 reads (73%) | catalogued as COSV100450374; called by muse, varscan2
- OSGIN1 | n.1511G>A | RNA (SNP) | VAF 74/128 reads (58%) | catalogued as rs766527071, COSV59420167; called by muse, mutect2, varscan2
- SNORD114-3 | n.65C>T | RNA (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
